Somatic mutation profile of tumor specimen TCGA-LN-A49M-01A (aliquot TCGA-LN-A49M-01A-21D-A27G-09) from TCGA case TCGA-LN-A49M, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 62.8 years (22,933 days).
Specimen TCGA-LN-A49M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6e981d0-23d0-4da3-af0f-c1eed2fc675e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49M-10A (Blood Derived Normal), aliquot TCGA-LN-A49M-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f22ee5fb-ace1-4fa1-81a5-567423bfad2b

The open-access MAF lists 251 somatic variants for this specimen: 181 protein-altering or splice-affecting, 63 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 63, Nonsense Mutation 19, Frame Shift Del 4, Translation Start Site 3, Intron 3, RNA 3, Splice Region 2, Frame Shift Ins 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L11 | c.467G>A p.G156E (on ENST00000393256 / NM_138621.5; = p.G96E on NM_006538.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58029627; called by muse, mutect2, varscan2
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 171/464 reads (37%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 129/327 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BNC2 | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV66140597; called by muse, mutect2, varscan2
- CDCA7 | c.1051C>T p.H351Y (on ENST00000347703 / NM_145810.3; = p.H430Y on NM_031942.5) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.904); catalogued as rs1223063236, COSV60721913; called by muse, mutect2, varscan2
- CDK13 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs1476149092; called by muse, mutect2, varscan2
- COL22A1 | c.4628C>G p.A1543G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as COSV100279232; called by muse, mutect2, varscan2
- CPAMD8 | c.3491G>A p.R1164Q (on ENST00000651564; = p.R1117Q on NM_015692.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs1315391248, COSV71596360; called by muse, mutect2, varscan2
- CTNNA1 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV57072774; called by muse, mutect2
- DAGLA | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs996254996, COSV57194975; called by muse, mutect2, varscan2
- DAPK1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1362592392; called by muse, mutect2, varscan2
- DDX21 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV62555563; called by muse, mutect2, varscan2
- DENND2A | c.1532C>G p.S511* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV52047900; called by muse, mutect2, varscan2
- DLGAP3 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs146229611, COSV52395742; called by muse, mutect2, varscan2
- DLGAP5 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs750563382; called by muse, mutect2, varscan2
- DSP | c.6325G>A p.E2109K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs397516951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECE1 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1313819749, COSV51664443; called by muse, mutect2, varscan2
- ENG | c.1811C>A p.A604D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as CM062599; called by muse, mutect2, varscan2
- GRIA1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs146865938; called by muse, mutect2, varscan2
- GRM4 | c.2106C>G p.I702M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1441600544; called by muse, mutect2, varscan2
- HHIP | c.1735C>T p.L579F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs1294275264; called by muse, mutect2, varscan2
- HMGXB4 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99330041; called by muse, mutect2, varscan2
- IFI27 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs755125237; called by muse, mutect2, varscan2
- IGHMBP2 | c.2828G>C p.R943T | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV54819863, COSV54820280, COSV54825435; called by muse, mutect2, varscan2
- IGLL1 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV99968680; called by muse, mutect2
- KCNQ3 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as rs764285990, COSV101195883; called by muse, mutect2, varscan2
- KRT17 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as rs749862409; called by muse, mutect2, varscan2
- KRT33A | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV50365634; called by muse, mutect2, varscan2
- MARF1 | c.4945G>T p.D1649Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60028536; called by muse, mutect2, varscan2
- MATN2 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs758729757, COSV54720384; called by muse, mutect2, varscan2
- MCHR2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs1015907823, COSV56002006, COSV99912673; called by muse, mutect2, varscan2
- MTA3 | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1558600896, COSV68135950; called by muse, mutect2, varscan2
- MUC16 | c.14270C>A p.P4757H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV67470288, COSV67477700; called by muse, mutect2, varscan2
- MYH10 | c.4632G>A p.M1544I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV99344274; called by muse, mutect2, varscan2
- MYOT | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV53513992; called by muse, mutect2, varscan2
- NBAS | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs149760582; called by muse, mutect2, varscan2
- NFATC2 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs779382116, COSV65352933; called by muse, mutect2, varscan2
- NQO2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs138748428; called by muse, mutect2, varscan2
- NUTM1 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs540031927; called by muse, mutect2, varscan2
- OLFM1 | c.1105G>A p.A369T (on ENST00000371793 / NM_001282611.2; = p.A351T on NM_014279.5) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.629); catalogued as COSV53282770; called by muse, mutect2, varscan2
- OPA1 | c.3013G>C p.D1005H (on ENST00000361510 / NM_130837.3; = p.D950H on NM_015560.3) | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as CD070499; called by muse, mutect2, varscan2
- OR2AK2 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.3); catalogued as COSV63557766; called by muse, mutect2, varscan2
- PAX7 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs1170293876; called by muse, mutect2, varscan2
- PCDHB14 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV53388026; called by muse, mutect2, varscan2
- PCDHB14 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.155); catalogued as rs782376418; called by muse, mutect2
- PRRC2A | c.4259G>C p.G1420A | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV65685762; called by muse, mutect2, varscan2
- PSMC4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.006); catalogued as COSV50094420, COSV50098231; called by muse, mutect2, varscan2
- PYGM | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs775674324; called by muse, mutect2, varscan2
- RFX5 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1421740629; called by muse, mutect2, varscan2
- RGS11 | c.1018C>T p.R340* (on ENST00000397770 / NM_183337.3; = p.R319* on NM_003834.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 122/334 reads (37%) | catalogued as rs746717778, COSV51453961; called by muse, mutect2, varscan2
- RNF185 | c.322C>G p.P108A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99839803; called by muse, mutect2, varscan2
- SACS | c.4507A>G p.M1503V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs755189624; called by muse, mutect2, varscan2
- SMC2 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104377168; called by muse, mutect2, varscan2
- SNF8 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as COSV99287803; called by muse, mutect2, varscan2
- STPG1 | c.236C>T p.P79L (on ENST00000337248 / NM_001199013.2; = p.P32L on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as rs138455088; called by muse, mutect2, varscan2
- STRADA | c.1273G>C p.E425Q (on ENST00000336174 / NM_001363786.1; = p.E388Q on NM_001003786.3) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs748003173; called by muse, mutect2, varscan2
- SYNRG | c.3248G>A p.R1083H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs939221527; called by muse, mutect2, varscan2
- TRHDE | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV53843941; called by muse, mutect2
- TRIOBP | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.061); catalogued as COSV60380396; called by muse, mutect2
- TRPM4 | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53260128; called by muse, mutect2, varscan2
- TRRAP | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62858814; called by muse, mutect2, varscan2
- TUBGCP2 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); catalogued as COSV53306655, COSV99427588; called by muse, mutect2, varscan2
- USF3 | c.3593C>A p.S1198Y | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV57069682; called by muse, mutect2, varscan2
- USP28 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV50204462; called by muse, mutect2, varscan2
- VPS13C | c.8359G>C p.E2787Q (on ENST00000644861 / NM_020821.3; = p.E2744Q on NM_017684.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51121215; called by muse, mutect2, varscan2
- YBX1 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as rs772212080; called by muse, mutect2, varscan2
- ZNF197 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as rs947084569; called by muse, mutect2, varscan2
- ZNF292 | c.6655G>A p.D2219N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60539019, COSV60545121; called by muse, mutect2, varscan2
- ZNF517 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV63464630; called by muse, mutect2, varscan2
- ADCK2 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- AHNAK | c.2726C>A p.S909* | Nonsense Mutation (SNP) | VAF 41/150 reads (27%) | called by muse, mutect2, varscan2
- AMOT | c.2408C>T p.S803F (on ENST00000371959 / NM_001113490.1; = p.S394F on NM_133265.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKRD54 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ARFGEF2 | c.1546A>G p.I516V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, varscan2
- ATG2B | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AVPR2 | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- BMP2K | c.2723A>G p.N908S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASD1 | c.2145T>A p.Y715* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- CCDC14 | c.1723G>A p.E575K (on ENST00000488653; = p.E527K on NM_022757.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CCT8L2 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CDH12 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- CEP152 | c.4402G>A p.E1468K (on ENST00000380950 / NM_001194998.2; = p.E1412K on NM_014985.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CEP250 | c.6345G>C p.E2115D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2
- CEP85L | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CERS2 | c.673_691del p.F225Lfs*4 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- CHD8 | c.6214G>C p.E2072Q (on ENST00000646647 / NM_001170629.2; = p.E1793Q on NM_020920.4) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CHRD | c.1221_1222del p.S408Cfs*6 | Frame Shift Del (DEL) | VAF 35/64 reads (55%) | called by mutect2, pindel, varscan2
- CLHC1 | c.496C>G p.P166A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNOT6L | c.1452C>A p.F484L (on ENST00000504123 / NM_001286790.2; = p.F479L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COCH | c.1497C>G p.I499M (on ENST00000216361 / NM_001347720.1; = p.I434M on NM_004086.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CPSF1 | c.2612T>C p.L871P | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CRPPA | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CWC27 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- CYP2W1 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCC | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- DDR1 | c.1882G>A p.E628K (on ENST00000324771; = p.E591K on NM_001954.4) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX28 | c.1516C>G p.P506A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DPYD | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- E2F5 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- EFCAB13 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2894A>T p.Q965L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- EIF4G2 | c.569A>T p.N190I | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ELAVL1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENG | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- EPB41L3 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- EPHA10 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- EWSR1 | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FER1L6 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- FLNA | c.3124G>T p.E1042* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- GCFC2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GLIS1 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- GLRA2 | c.874A>T p.T292S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HIVEP1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- HOXC4 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL6ST | c.1747_1751del p.T583* | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- INTS7 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KDM4C | c.2123A>T p.E708V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- KIDINS220 | c.1594T>G p.F532V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF7 | c.3931G>A p.E1311K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, varscan2
- KMT5C | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- LRRN2 | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MAGEC2 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MAP7D2 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- MARCHF6 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MARK1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MARVELD3 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED13 | c.5831dup p.M1944Ifs*36 | Frame Shift Ins (INS) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- METTL25 | c.264G>C p.M88I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTMR4 | c.1438T>A p.L480M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MTOR | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MYH7 | c.4438G>C p.E1480Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFS8 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP5 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NSMAF | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PABPC4 | c.783_784del p.F262Cfs*19 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by pindel, varscan2
- PCDHB9 | c.1002G>C p.L334F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PHC3 | c.2585C>G p.S862C (on ENST00000494943 / NM_001308116.2; = p.S874C on NM_024947.4) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PIK3R5 | c.1261T>A p.F421I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PIR | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRIM1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRMT7 | c.406dup p.C136Lfs*12 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- PRPF8 | c.5455C>G p.L1819V | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPRU | c.2774-1G>A p.X925_splice | Splice Site (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- PXN | c.1309C>T p.H437Y (on ENST00000228307 / NM_001080855.3; = p.H403Y on NM_002859.4) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCC1L | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPF1 | c.704G>C p.R235T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RPL10L | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RPS6KA6 | c.1319G>T p.C440F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- RTBDN | c.98C>G p.P33R (on ENST00000393233 / NM_001270444.1; = p.P65R on NM_031429.2) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- RYR1 | c.13751C>G p.S4584* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- SCAPER | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SCEL | c.1567C>T p.Q523* (on ENST00000349847 / NM_144777.3; = p.Q503* on NM_003843.4) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- SLC16A4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC16A7 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- SLC44A2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SLC7A13 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SNAPC4 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRP54 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SV2C | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2
- SYNJ1 | c.3928A>T p.M1310L | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D10B | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TEK | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TEX11 | c.1450G>A p.E484K (on ENST00000344304; = p.E469K on NM_031276.3) | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- THAP3 | c.669C>G p.C223W (on ENST00000054650 / NM_001195753.1; = p.C222W on NM_001195752.1) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.135); called by muse, mutect2
- TNS4 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- TRPV5 | c.1284C>T p.I428= | Splice Region (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- TUBA3D | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TXNRD1 | c.1884A>G p.V628= (on ENST00000525566 / NM_001093771.3; = p.V530= on NM_003330.4) | Splice Region (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- VCL | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- VPS26C | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VTA1 | c.763A>C p.N255H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VWA3A | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YBX2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZC3H12B | c.1654T>C p.F552L | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF14 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZNF546 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF597 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF710 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF791 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- AC131160.1 | c.117C>T p.L39= | Silent (SNP) | VAF 84/163 reads (52%) | catalogued as rs1295734101, COSV100226410; called by muse, mutect2, varscan2
- AHNAK | c.12030G>C p.L4010= | Silent (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- ALPI | c.426G>A p.T142= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99786150; called by muse, mutect2, varscan2
- APBA2 | c.1986C>T p.I662= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ARID1A | c.2166C>T p.N722= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV61387847; called by muse, mutect2, varscan2
- AWAT2 | c.219G>C p.V73= | Silent (SNP) | VAF 27/42 reads (64%) | called by muse, mutect2, varscan2
- C15orf39 | c.1701A>G p.S567= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- CACNB3 | c.255C>G p.V85= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- CCT2 | c.99C>T p.I33= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs780733349, COSV54741127; called by muse, mutect2, varscan2
- CDYL | c.1434C>T p.F478= (on ENST00000328908 / NM_001368125.1; = p.F424= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs372837191, COSV59358215; called by muse, mutect2, varscan2
- CEP250 | c.4395G>A p.L1465= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs377306728; called by muse, mutect2, varscan2
- CRCP | c.357C>T p.T119= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs758222904; called by mutect2, varscan2
- CREB3L2 | c.54G>A p.L18= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs924686907; called by muse, mutect2, varscan2
- CSMD1 | c.8811T>C p.F2937= (on ENST00000520002; = p.F2936= on NM_033225.6) | Silent (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- CYP1A1 | c.654C>G p.V218= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV65697706; called by muse, mutect2, varscan2
- DCAF4L2 | c.117C>T p.F39= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as rs779092689, COSV60476339; called by muse, mutect2, varscan2
- ECI1 | c.258G>A p.E86= | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- GPN2 | c.327C>T p.F109= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as rs753428953, COSV64652839; called by muse, mutect2, varscan2
- GRIK2 | c.1702C>T p.L568= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- HEATR9 | c.1059C>G p.L353= | Silent (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- HSDL1 | c.276C>A p.L92= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- IGF2R | c.5712C>G p.V1904= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- KIFC1 | c.1734C>T p.L578= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs774299603, COSV65729299; called by muse, mutect2, varscan2
- LAP3 | c.57G>C p.V19= | Silent (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- LCMT1 | c.921G>T p.L307= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1205791848; called by muse, mutect2, varscan2
- LRBA | c.7281T>C p.I2427= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- LRRTM3 | c.1620C>T p.L540= | Silent (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- LSM10 | c.51G>C p.L17= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1329361481; called by muse, mutect2, varscan2
- LTB4R | c.459C>G p.L153= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs375670032, COSV51865274; called by muse, mutect2, varscan2
- LYSMD1 | c.477G>A p.K159= | Silent (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- MYLIP | c.12T>C p.Y4= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- MYPN | c.3567G>A p.V1189= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1308500781; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFE2L1 | c.951C>T p.L317= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs374254839; called by muse, mutect2, varscan2
- OR4C6 | c.276C>T p.L92= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs748058915, COSV58602553, COSV58605502; called by muse, mutect2, varscan2
- OR4K1 | c.228T>C p.F76= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- OR4N2 | c.291C>T p.C97= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as rs766308802, COSV60050258, COSV60051167; called by muse, mutect2, varscan2
- PDPR | c.2148G>A p.E716= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1251771521; called by muse, mutect2, varscan2
- PHACTR3 | c.666G>A p.E222= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- PKM | c.420C>T p.L140= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs879124422; called by muse, mutect2, varscan2
- PLAUR | c.345C>T p.L115= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1201057384, COSV99654979; called by muse, mutect2, varscan2
- PLK3 | c.1314G>C p.L438= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- PNPLA3 | c.744C>T p.F248= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV53380911; called by muse, mutect2, varscan2
- PRM2 | c.108G>A p.L36= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs752229574; called by muse, mutect2, varscan2
- PTPN11 | c.1245C>A p.V415= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- PTPN13 | c.4158G>A p.V1386= (on ENST00000411767 / NM_080683.3; = p.V1367= on NM_006264.3) | Silent (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2, varscan2
- RCOR3 | c.852G>A p.Q284= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- RPRM | c.174G>A p.Q58= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- RSF1 | c.3684G>A p.K1228= | Silent (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- RUNDC3B | c.1020G>A p.K340= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- SCAPER | c.843G>A p.V281= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- SLC1A6 | c.178C>T p.L60= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99693893; called by muse, mutect2, varscan2
- SLC24A1 | c.2751C>T p.I917= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs368057501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENT4B | c.1935T>C p.T645= (on ENST00000561678 / NM_001365323.2; = p.T630= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.596G>A p.*199= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs910901874; called by muse, mutect2
- TNRC18 | c.2100G>A p.L700= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV68087527; called by muse, varscan2
- TRAJ9 | c.18C>T p.F6= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.1218G>A p.L406= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.159C>T p.G53= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1367693905, COSV60406020; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ULK2 | c.1899G>A p.S633= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as rs201972720, COSV64447614; called by muse, mutect2, varscan2
- WDR91 | c.1458C>T p.L486= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- WNT10A | c.1203C>T p.F401= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs1273885096, COSV99297611; called by muse, mutect2, varscan2
- ZBTB17 | c.975C>T p.I325= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- ZNF695 | c.693G>A p.K231= | Silent (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- FAM183BP | n.1236G>A | RNA (SNP) | VAF 20/71 reads (28%) | catalogued as rs777801963; called by muse, mutect2, varscan2
- KPNA4 | c.1032+392G>A | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100515221; called by muse, mutect2, varscan2
- MIR509-2 | n.54A>C | RNA (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139687 G>C | 5'Flank (SNP) | VAF 19/51 reads (37%) | catalogued as rs1420001488; called by muse, mutect2, varscan2
- SNORD114-5 | n.10G>A | RNA (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1458G>A | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- TPM3 | c.244-6823C>T | Intron (SNP) | VAF 17/50 reads (34%) | catalogued as rs749857209, COSV99666572; called by muse, mutect2, varscan2
